Gene-level copy-number profile of tumor specimen TCGA-13-0903-01A from TCGA case TCGA-13-0903, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 43.0 years (15,705 days).
Specimen TCGA-13-0903-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.2430260f-1a0f-477e-83a4-4b18babf2a98.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0903-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ee1af929-b653-4935-8138-f84cfc156d0a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 17,886; copy number 2: 35,955; copy number 3: 4,685; copy number 4: 877; copy number 5: 410.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-0903-01A-01D-0399-01): tumor purity 0.88, ploidy 1.86, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:14,774,469–14,777,727, 1 gene: AL031293.1.
- chr3:175,234,861–175,271,096, 1 gene: NAALADL2-AS2.
- chr14:61,529,128–61,695,823, 5 genes: AL355916.3, AL355916.2, LINC01303, AL355916.1, HIF1A-AS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 410 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:25,593,304–25,756,256, 3 genes, copy number 5 (within-gene range 3–5): AC005165.1, AC005165.2, AC005165.3.
- chr8:123,416,726–145,066,685, 407 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 17,663. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
